TCGA case TCGA-KN-8430 — Kidney Chromophobe (TCGA-KICH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Harvard. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9f8aa332-e625-46f7-b77b-1fcb3ca99ee2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 75 years; Vital status: Dead.

Diagnoses (2)
1. Renal cell carcinoma, chromophobe type (the primary disease): ICD-O-3 morphology code: 8317/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 75.2 years (27,467 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC clinical M: M0; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic stage: Stage I; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the pleura (histology not recorded by GDC). Laterality: Right; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Pemetrexed Disodium; Days to treatment start: 139 days; Treatment anatomic sites: Body, total.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Disease response: With Tumor; Timepoint: Follow-up.

Molecular and laboratory tests
- Calcium: Low.
- Leukocytes: Normal.
- Hemoglobin: Low.
- Platelets: Normal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-KN-8430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.2; Shortest dimension: 0.3.
  Slide TCGA-KN-8430-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-KN-8430-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-KN-8430-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-KN-8430-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.4; Shortest dimension: 0.3.
  Slide TCGA-KN-8430-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lymph nodes examined: No; Tumor status: With tumor; Serum calcium level: Low; Hemoglobin level: Low; Tobacco smoking history indicator: 1.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Pleura; Other malignancy histological type: Epithelioid.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -85.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: ALIMTA (PEMETREXED INJECTION).

GDC annotations on this case (curator notes; quoted as recorded):
- History of unacceptable prior treatment related to a prior/other malignancy: Prior malignancy epitheliod cancer R pleura treated with Alimta.
- Prior malignancy: Prior malignancy epitheliod cancer R pleura treated with Alimta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), time not recorded; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), time not recorded; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), time not recorded.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-KN-8430-01): tumor purity 0.85, ploidy 1.48, whole-genome doublings 0 (call status: maf_call).
